Somatic mutation profile of tumor specimen TARGET-10-PATGZA-09A (aliquot TARGET-10-PATGZA-09A-01D) from TARGET case TARGET-10-PATGZA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,253 days).
Specimen TARGET-10-PATGZA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12d80e2-d9df-40f9-a84a-dadca6a2fe1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGZA-10A (Blood Derived Normal), aliquot TARGET-10-PATGZA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae033f7d-b2c3-4289-a8eb-e1fd4983a0e5

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 4, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL3 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146531280, COSV54474615; called by muse, mutect2, varscan2
- ADGRF3 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61054217; called by muse, mutect2, varscan2
- CACNA1H | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1257816523, COSV62007495; called by muse, mutect2
- CBR1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1048322369, COSV51738553; called by muse, mutect2, varscan2
- CFAP57 | c.2738G>A p.R913Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1216005678, COSV65265785; called by muse, mutect2, varscan2
- CLTC | c.3239C>G p.S1080* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV52254542; called by muse, mutect2, varscan2
- HECTD1 | c.3521G>T p.G1174V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67949948; called by muse, mutect2, varscan2
- KMT2E | c.3039_3048del p.C1013* | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | catalogued as COSV57581731; called by mutect2, pindel, varscan2
- KNL1 | c.3335T>C p.M1112T (on ENST00000346991 / NM_170589.5; = p.M1086T on NM_144508.5) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1308800528, COSV61162058; called by muse, mutect2, varscan2
- LRP1 | c.8720C>G p.S2907W | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54529992; called by muse, mutect2, varscan2
- LRRIQ3 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV104417023, COSV63051593; called by muse, mutect2, varscan2
- METTL15 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57725160; called by muse, mutect2, varscan2
- NKX2-2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as rs762587716, COSV65820576; called by muse, mutect2, varscan2
- NXPE3 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs1446190351, COSV56292922; called by muse, mutect2, varscan2
- OR6A2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs778988808, COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- PIK3R3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs569257270, COSV53107849; called by muse, mutect2, varscan2
- SLIT2 | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as COSV56564709; called by muse, mutect2, varscan2
- SP140L | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54749606; called by muse, mutect2, varscan2
- TAF1L | c.4525C>T p.R1509C | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs775083365, COSV54271897; called by muse, mutect2, varscan2
- TEX15 | c.4400C>T p.A1467V (on ENST00000256246; = p.A1850V on NM_001350162.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs768140607, COSV56355883; called by muse, mutect2, varscan2
- TLN2 | c.3787C>T p.R1263W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745410904, COSV60897809; called by muse, mutect2, varscan2
- ZAR1L | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs1199309786; called by muse, mutect2, varscan2
- ETV6 | c.312_313insAG p.R105Sfs*18 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel*, varscan2
- ZBTB11 | c.2509T>A p.F837I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2
- ARC | c.1113G>A p.P371= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs371075422, COSV63077995; called by muse, varscan2
- ITGA2B | c.1401C>T p.I467= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs766997708, COSV52231081, COSV52234954; called by muse, mutect2, varscan2
- KRT36 | c.276C>T p.S92= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs750005828; called by muse, mutect2, varscan2
- PLXDC2 | c.963G>A p.E321= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs1316764130; called by muse, mutect2, varscan2
- SMARCD2 | c.795C>T p.Y265= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs371465181; called by muse, mutect2, varscan2
- TMEM217 | c.291C>T p.Y97= | Silent (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- ZNF518A | c.783C>G p.P261= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100283443, COSV60153511; called by muse, mutect2, varscan2
- CNP | c.677-114G>A | Intron (SNP) | VAF 13/30 reads (43%) | catalogued as rs1335841942; called by muse, mutect2, varscan2
- DHRS2 | c.676-23C>T | Intron (SNP) | VAF 12/28 reads (43%) | catalogued as rs780655629; called by muse, mutect2, varscan2
- EIF4A1 | c.515-10dup | Intron (INS) | VAF 32/74 reads (43%) | catalogued as rs767835311; called by mutect2, varscan2
- TMX2 | c.250+105G>A | Intron (SNP) | VAF 36/86 reads (42%) | catalogued as rs764820789; called by muse, mutect2, varscan2
